Gene-level copy-number profile of tumor specimen ALCH-B2NM-TTP1-A from ALCHEMIST case ALCH-B2NM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.9 years (27,705 days).
Specimen ALCH-B2NM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3b9fbbf6-215c-4165-aa4b-0f24f55c0d51.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2NM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/6b52672c-5aeb-4515-a03e-474bd2890025

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 74; copy number 2: 24,207; copy number 3: 9,181; copy number 4: 19,232; copy number 5: 2,720; copy number 6: 2,508; copy number 7: 429; copy number 8: 22; copy number 9: 69; copy number 10: 231; copy number 11: 9; copy number 14: 39; copy number 15: 33; copy number 17: 29; copy number 22: 1; copy number 23: 25; copy number 25: 5; copy number 30: 5; copy number 32: 5; copy number 34: 1; copy number 35: 2; copy number 37: 3; copy number 48: 5; copy number 49: 3; copy number 72: 4.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,848,318–9,850,154, 1 gene (within-gene range 0–2): AL357140.1.
- chr3:71,943,592–72,279,503, 1 gene (within-gene range 0–2): LINC00877.
- chr3:72,061,061–72,446,623, 9 genes (within-gene range 0–2): AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.1, RYBP.
- chr4:69,306,469–69,358,177, 2 genes (within-gene range 0–1): AC114786.3, AC114786.2.
- chr5:101,581,830–101,582,128, 1 gene: RN7SL802P.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr9:97,386,240–97,396,112, 1 gene: AL512590.1.
- chr11:45,885,651–45,918,812, 4 genes: MAPK8IP1, AC068385.1, C11orf94, PEX16.
- chr11:65,561,484–65,592,650, 5 genes (within-gene range 0–2): AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1.
- chr11:67,428,460–67,443,821, 4 genes: RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B.
- chr15:41,825,099–41,848,155, 3 genes (within-gene range 0–4): AC020659.2, JMJD7, JMJD7-PLA2G4B.
- chr16:86,192,793–86,349,688, 7 genes (within-gene range 0–2): AC135012.3, LINC01082, LINC01081, Y_RNA, LINC02135, LINC00917, AC092327.2.
- chr17:81,480,523–81,481,570, 1 gene: LINC01971.
- chr19:7,476,875–7,497,449, 1 gene (within-gene range 0–2): PEX11G.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,145 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–1,273,864, 92 genes, copy number 5 (broad region; genes not listed).
- chr1:1,280,436–2,050,070, 53 genes, copy number 7: SCNN1D, ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808, MXRA8, AURKAIP1, NDUFB4P8, CCNL2, MRPL20-AS1, MRPL20, RN7SL657P, MRPL20-DT, ANKRD65, AL391244.1, TMEM88B, LINC01770, VWA1, ATAD3C, ATAD3B, ATAD3A, TMEM240, SSU72, AL645728.1, AL691432.3, FNDC10, AL691432.2, MIB2, MMP23B, CDK11B, FO704657.1, SLC35E2B, AL691432.1, MMP23A, CDK11A, AL031282.2, AL031282.1, SLC35E2A, NADK, GNB1, AL109917.1, CALML6, TMEM52, CFAP74, AL391845.2, GABRD, AL391845.1.
- chr1:3,454,665–8,796,673, 101 genes, copy number 5–7 (broad region; genes not listed).
- chr1:39,757,182–40,466,767, 27 genes, copy number 5–72 (within-gene range 2–72): BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, ZFP69B, AL031985.3.
- chr1:44,030,437–46,370,955, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:119,230,313–121,580,524, 69 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:234,957,231–235,504,452, 20 genes, copy number 5: AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE, RPS21P1, B3GALNT2.
- chr2:43,001,355–48,776,517, 121 genes, copy number 5 (broad region; genes not listed).
- chr2:52,474,073–52,961,452, 8 genes, copy number 7 (within-gene range 7–11): GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr2:54,330,034–64,332,801, 161 genes, copy number 5–7 (broad region; genes not listed).
- chr2:218,419,121–219,403,633, 57 genes, copy number 5: VIL1, USP37, RN7SKP38, CNOT9, RNU6-136P, PLCD4, ZNF142, BCS1L, RNF25, STK36, TTLL4, CYP27A1, AC009974.2, AC009974.1, PRKAG3, MIR9500, RPL23AP31, WNT6, WNT10A, LINC01494, RNU6-642P, AC097468.2, KRT8P30, CDK5R2, LINC00608, FEV, CRYBA2, MIR375, AC097468.1, CFAP65, IHH, MIR3131, AC097468.3, NHEJ1, AC068946.1, RN7SL764P, SLC23A3, CNPPD1, RETREG2, ZFAND2B, AC068946.3, ABCB6, AC068946.2, ATG9A, ANKZF1, GLB1L, STK16, TUBA4A, TUBA4B, DNAJB2, PTPRN, MIR153-1, AC114803.1, RESP18, AC053503.2, DNPEP, AC053503.1.
- chr3:129,647,792–129,918,575, 5 genes, copy number 6: TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1.
- chr3:133,400,056–134,321,171, 23 genes, copy number 6: BFSP2, AC055753.1, BFSP2-AS1, AC022296.2, AC022296.4, AC022296.3, AC022296.1, CDV3, TOPBP1, INHCAP, RNU6-678P, RNA5SP140, TF, AC080128.1, SRPRB, AC080128.2, RAB6B, C3orf36, SLCO2A1, LINC02000, RYK, HMGB3P14, LINC02004.
- chr3:136,336,236–138,115,818, 25 genes, copy number 6–7 (within-gene range 4–7): STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36.
- chr3:141,228,726–173,336,965, 485 genes, copy number 6 (broad region; genes not listed).
- chr3:175,059,361–198,123,232, 483 genes, copy number 5–17 (broad region; genes not listed).
- chr4:53,377,641–57,207,459, 89 genes, copy number 6–30 (within-gene range 2–30) (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr6:116,453,014–164,348,644, 698 genes, copy number 5 (broad region; genes not listed).
- chr7:91,940,862–92,401,383, 11 genes, copy number 5: AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1.
- chr8:37,784,191–43,077,334, 126 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr8:140,657,900–145,066,685, 191 genes, copy number 5 (broad region; genes not listed).
- chr9:12,134–11,276,314, 155 genes, copy number 5–6 (broad region; genes not listed).
- chr9:41,233,755–42,973,289, 52 genes, copy number 6–25: MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4.
- chr9:63,581,254–64,889,063, 33 genes, copy number 6: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr12:12,310–26,421,462, 668 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:55,716,036–57,586,633, 121 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:39,053,019–39,791,665, 5 genes, copy number 5 (within-gene range 2–5): AL354809.1, NXT1P1, LHFPL6, COG6, MIR4305.
- chr17:4,004,445–4,366,628, 11 genes, copy number 5: ZZEF1, RNA5SP434, CYB5D2, ANKFY1, AC087292.1, Y_RNA, RYKP1, AC087742.1, UBE2G1, MFSD1P1, RN7SL774P.
- chr17:15,944,917–16,218,185, 11 genes, copy number 5 (within-gene range 4–5): ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P.
- chr17:42,458,844–42,648,738, 20 genes, copy number 6: ATP6V0A1, MIR548AT, AC107993.1, AC067852.3, MIR5010, PTP4A2P1, NAGLU, AC067852.1, HSD17B1P1, AC067852.2, HSD17B1, COASY, MLX, PSMC3IP, AC067852.5, RETREG3, AC067852.4, TUBG1, ATP5MGP7, HMGB3P27.
- chr17:64,477,785–73,092,712, 165 genes, copy number 5–14 (broad region; genes not listed).
- chr18:39,841,174–80,247,514, 560 genes, copy number 6 (broad region; genes not listed).
- chr19:14,305,458–15,022,990, 36 genes, copy number 5 (within-gene range 2–5): LINC01841, LINC01842, ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6.
- chr19:40,665,905–41,835,950, 74 genes, copy number 5 (broad region; genes not listed).
- chr19:44,747,705–51,826,190, 457 genes, copy number 5 (broad region; genes not listed).
- chr19:54,953,130–55,881,855, 75 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:12,999,676–13,113,790, 4 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P.
- chr21:43,414,483–43,479,534, 4 genes, copy number 8–30: SIK1, LINC00319, LINC00313, AP001048.1.
- chr22:49,960,768–50,801,309, 52 genes, copy number 5: PIM3, MIR6821, IL17REL, TTLL8, MLC1, MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12, MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2, PPP6R2, SBF1, ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 72. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
